Somatic mutation profile of tumor specimen TCGA-CA-6718-01A (aliquot TCGA-CA-6718-01A-11D-1835-10) from TCGA case TCGA-CA-6718, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.8 years (17,109 days).
Specimen TCGA-CA-6718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca5202b-fd49-4d75-8357-40aec6d3b3e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-6718-10A (Blood Derived Normal), aliquot TCGA-CA-6718-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d2bad3-5c00-42c3-91b9-e30c05ac6c1d

The open-access MAF lists 3,930 somatic variants for this specimen: 2,974 protein-altering or splice-affecting, 554 silent, 402 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,474, Silent 554, Nonsense Mutation 433, 3'UTR 181, Intron 123, RNA 38, 5'UTR 35, Splice Site 27, Splice Region 23, 3'Flank 13, 5'Flank 12, Frame Shift Ins 8.

Variants (750 of 3,930; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs765429911, CM109595, COSV64671812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 15/59 reads (25%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.4054C>T p.R1352W | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794858, COSV100802739, COSV64192374; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- FOXP1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs763413735, COSV59534728; called by muse, mutect2, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, varscan2
- GRIN2B | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307547, COSV74205114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 53/78 reads (68%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- NFIX | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs786205515, COSV62175946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3141T>G p.H1047Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1057519932, COSV55875891, COSV55920782; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | hotspot (GDC flag); catalogued as rs1554898097, COSV64289174; ClinVar: pathogenic; called by muse, varscan2
- SMAD4 | c.1601A>C p.Q534P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV61687582; called by muse, mutect2, varscan2
- STAT1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs387906758, CM115708, CM133368; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WWOX | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs751181600, COSV63434227; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZNF649 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 30/129 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56814561; called by muse, mutect2, varscan2
- AADAC | c.703A>C p.N235H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV51758438; called by muse, mutect2, varscan2
- AARS2 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs766085905, COSV55113832; called by muse, mutect2, varscan2
- ABCA10 | c.4584A>C p.K1528N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV52219448; called by muse, mutect2, varscan2
- ABCA10 | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV52219460; called by muse, mutect2, varscan2
- ABCA12 | c.731A>C p.Q244P | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV55952044; called by muse, mutect2
- ABCA12 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866662919, COSV55952052, COSV55970111, COSV55974804; called by muse, mutect2, varscan2
- ABCA13 | c.7048G>T p.E2350* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV71284578, COSV71286769; called by muse, mutect2, varscan2
- ABCA13 | c.10788G>T p.E3596D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71284582; called by muse, mutect2, varscan2
- ABCA13 | c.14215G>T p.D4739Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV68944326; called by muse, mutect2, varscan2
- ABCA9 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV60621955; called by muse, mutect2, varscan2
- ABCB4 | c.2016A>C p.K672N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55933155; called by muse, mutect2, varscan2
- ABCB5 | c.425A>C p.Q142P | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.522); catalogued as COSV51705273; called by muse, mutect2, varscan2
- ABCB7 | c.340G>T p.D114Y (on ENST00000373394 / NM_001271696.3; = p.D115Y on NM_004299.6) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV53718464; called by muse, mutect2, varscan2
- ABCB9 | c.2086A>G p.I696V (on ENST00000280560 / NM_019625.4; = p.I653V on NM_019624.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54890667; called by muse, mutect2, varscan2
- ABCC12 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV60911644; called by muse, mutect2, varscan2
- ABCC5 | c.1545A>C p.K515N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55588080; called by muse, mutect2, varscan2
- ABCC6 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52742062; called by muse, mutect2, varscan2
- ABCD2 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV58050526; called by muse, mutect2, varscan2
- ABHD5 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV50006356; called by muse, varscan2
- ABI3 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV56799434; called by muse, mutect2, varscan2
- AC006059.2 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59606331; called by muse, varscan2
- AC008676.3 | c.404T>G p.F135C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV56636056; called by muse, mutect2, varscan2
- ACADSB | c.520T>G p.F174V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV62550415; called by muse, mutect2, varscan2
- ACAN | c.4255C>A p.L1419I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.155); catalogued as COSV61357513; called by muse, varscan2
- ACAP3 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61221672; called by muse, mutect2, varscan2
- ACE | c.2781C>A p.F927L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52005221; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by mutect2, varscan2
- ACOT13 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57763864; called by muse, mutect2, varscan2
- ACOX1 | c.287T>G p.F96C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53131788; called by muse, mutect2, varscan2
- ACSL6 | c.286T>C p.F96L (on ENST00000379240; = p.F121L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57295600; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM1 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1438641945, COSV54633540; called by muse, mutect2, varscan2
- ACSS3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 34/139 reads (24%) | catalogued as COSV54086888, COSV54087221, COSV54089111; called by muse, mutect2, varscan2
- ACTL7A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as rs367785686; called by muse, mutect2, varscan2
- ACTL9 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61005154; called by muse, mutect2, varscan2
- ACTN2 | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV63973108; called by muse, mutect2, varscan2
- ACVR2A | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV54020088; called by muse, mutect2, varscan2
- ADAL | c.416T>G p.I139S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101052600; called by mutect2, varscan2
- ADAM10 | c.1166T>G p.F389C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53049809; called by muse, mutect2, varscan2
- ADAM17 | c.1970A>C p.D657A | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV60397947; called by muse, mutect2, varscan2
- ADAM19 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1194445214, COSV57424556; called by muse, mutect2, varscan2
- ADAM21 | c.1548G>T p.E516D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV50789473, COSV99960652; called by muse, varscan2
- ADAM21 | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs1054849669, COSV50789314, COSV99960855; called by muse, mutect2, varscan2
- ADAM29 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs748743733, COSV63659968; called by muse, mutect2, varscan2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM7 | c.2219G>T p.S740I | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV51536398; called by muse, mutect2, varscan2
- ADAM9 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs760058275, COSV65946602; called by muse, mutect2, varscan2
- ADAMDEC1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV56474525; called by muse, mutect2, varscan2
- ADAMTS13 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV52469099; called by muse, mutect2, varscan2
- ADAMTS18 | c.2883G>T p.K961N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51400621; called by muse, mutect2, varscan2
- ADAMTS18 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs747773771, COSV51398816; called by mutect2, varscan2
- ADAMTS20 | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV67128809, COSV67131706; called by muse, mutect2, varscan2
- ADAMTS20 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV67134539; called by mutect2, varscan2
- ADAMTS20 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV67129169; called by muse, mutect2, varscan2
- ADAMTSL3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54442020; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4951C>A p.L1651I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as COSV54439799; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs375355414, COSV54996602; called by muse, mutect2, varscan2
- ADCY9 | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142301454; called by mutect2, varscan2
- ADGRB3 | c.1097G>T p.R366I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65387208, COSV65406072; called by muse, mutect2, varscan2
- ADGRB3 | c.4160T>G p.F1387C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.169); catalogued as COSV53237876; called by muse, mutect2, varscan2
- ADGRG2 | c.2591T>G p.F864C (on ENST00000379869 / NM_001079858.3; = p.F861C on NM_005756.4) | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61337991; called by muse, mutect2, varscan2
- ADGRG2 | c.2113C>A p.L705I (on ENST00000379869 / NM_001079858.3; = p.L702I on NM_005756.4) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61337999; called by muse, mutect2, varscan2
- ADGRG4 | c.2396T>G p.F799C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54951564; called by muse, mutect2, varscan2
- ADGRG4 | c.8619dup p.D2874Rfs*16 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | catalogued as rs1569338573; called by mutect2, pindel, varscan2
- ADGRV1 | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67994054; called by muse, mutect2, varscan2
- ADGRV1 | c.9094C>A p.L3032I | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV67978992, COSV67980365; called by muse, mutect2, varscan2
- ADGRV1 | c.14414C>T p.S4805L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs376076666; called by muse, mutect2, varscan2
- ADGRV1 | c.15818C>T p.A5273V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs766812068, COSV67980379; called by muse, mutect2, varscan2
- ADH5 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56447461; called by muse, mutect2, varscan2
- ADRB3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750693990, COSV61461592; called by muse, mutect2, varscan2
- AFF4 | c.193T>G p.F65V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54792614, COSV54798622; called by muse, mutect2, varscan2
- AFG3L2 | c.243A>C p.K81N | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV52313149; called by muse, mutect2, varscan2
- AFM | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.739); catalogued as COSV56919360; called by muse, mutect2, varscan2
- AFM | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56919366; called by muse, mutect2, varscan2
- AFP | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs897317988, COSV56924308; called by muse, mutect2, varscan2
- AGBL3 | c.1398G>T p.E466D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1451003053; called by muse, mutect2, varscan2
- AGFG1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as COSV59510662; called by muse, mutect2, varscan2
- AGGF1 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 28/479 reads (6%) | catalogued as COSV100462344; called by muse, mutect2
- AGR2 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV68596258; called by muse, mutect2, varscan2
- AGT | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64184063; called by muse, mutect2, varscan2
- AHCYL1 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63208349; called by muse, mutect2, varscan2
- AHNAK | c.16969A>C p.T5657P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57206424; called by muse, mutect2, varscan2
- AHNAK | c.15085C>A p.H5029N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.174); catalogued as COSV57206434; called by muse, mutect2, varscan2
- AHNAK | c.13750C>T p.P4584S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs147093523; called by muse, mutect2, varscan2
- AHNAK2 | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs776115130, COSV60910276; called by muse, mutect2, varscan2
- AHRR | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as rs762740242; called by muse, mutect2, varscan2
- AIDA | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV60663248; called by muse, mutect2, varscan2
- AK9 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as COSV58139373; called by muse, mutect2, varscan2
- AKAP11 | c.3391G>T p.E1131* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV50293608; called by muse, mutect2, varscan2
- AKAP12 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53571248; called by muse, mutect2, varscan2
- AKAP12 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99482971; called by muse, mutect2, varscan2
- AKAP12 | c.2072G>T p.R691I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752036291, COSV53570308; called by muse, mutect2, varscan2
- AKAP13 | c.4754G>A p.R1585Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs181593659, COSV63465642; called by muse, mutect2, varscan2
- AKAP4 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV62073922; called by muse, mutect2, varscan2
- AKAP4 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs781841685, COSV62073927; called by muse, mutect2, varscan2
- AKAP6 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55207551; called by muse, mutect2, varscan2
- AKAP6 | c.3265G>T p.E1089* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV55206281; called by muse, varscan2
- AKAP9 | c.6464A>G p.D2155G (on ENST00000359028; = p.D2123G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62341092; called by muse, mutect2, varscan2
- AKR1B15 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71151206; called by muse, mutect2, varscan2
- AKR1C8P | c.391T>G p.L131V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1397433117; called by mutect2, varscan2
- AKT3 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55630816; called by muse, varscan2
- AL592490.1 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV69425156; called by muse, mutect2, varscan2
- ALCAM | c.1038T>G p.I346M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV60246238; called by muse, mutect2, varscan2
- ALDH1L2 | c.2617A>C p.K873Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV51554048; called by muse, mutect2, varscan2
- ALDH1L2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as rs753144208, COSV51553573, COSV99311397; called by muse, mutect2, varscan2
- ALDH3B2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs149110344; called by muse, mutect2, varscan2
- ALDH9A1 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61339331; called by muse, mutect2, varscan2
- ALG14 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs767402341, COSV64635180; called by muse, mutect2, varscan2
- ALG5 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs908081645; called by mutect2, varscan2
- ALKBH8 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52833924; called by muse, mutect2, varscan2
- ALLC | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757104090, COSV52993453; called by muse, varscan2
- ALMS1 | c.8339C>A p.S2780* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV52504891, COSV52507149; called by muse, mutect2, varscan2
- ALOX15B | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.588); catalogued as COSV66479142; called by muse, mutect2, varscan2
- ALPI | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV55013872; called by muse, mutect2, varscan2
- ALPK2 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV64491095; called by muse, mutect2, varscan2
- ALPL | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66375990, COSV66376187; called by muse, mutect2, varscan2
- ALS2 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs750622240, COSV99970206; called by mutect2, varscan2
- AMIGO2 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56973538; called by muse, mutect2, varscan2
- AMIGO3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57537835; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMPD1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV62414895, COSV62415216, COSV62415333; called by muse, mutect2, varscan2
- AMPD3 | c.228A>C p.K76N (on ENST00000396553 / NM_001025389.2; = p.K85N on NM_000480.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67330163; called by muse, mutect2, varscan2
- ANAPC1 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61974736; called by muse, mutect2, varscan2
- ANGPT2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57335309; called by mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANKAR | c.4020G>T p.K1340N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV51461977; called by muse, mutect2, varscan2
- ANKFN1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757619098, COSV59442842; called by muse, mutect2, varscan2
- ANKRD11 | c.4456C>T p.R1486W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs189656772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.4106T>G p.F1369C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50820390; called by muse, mutect2, varscan2
- ANKRD17 | c.5891C>A p.S1964Y | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV58217109; called by muse, mutect2, varscan2
- ANKRD18B | c.2576A>C p.K859T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV52086253; called by mutect2, varscan2
- ANKRD30A | c.1479G>T p.K493N (on ENST00000611781; = p.K437N on NM_052997.2) | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV64606200; called by muse, mutect2, varscan2
- ANKRD30A | c.1778A>C p.K593T (on ENST00000611781; = p.K537T on NM_052997.2) | Missense Mutation (SNP) | VAF 96/978 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs779509544, COSV64606210; called by muse, mutect2
- ANKRD35 | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV62909802; called by muse, varscan2
- ANKRD36B | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 65/478 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs765994654; called by muse, mutect2, varscan2
- ANKS1B | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775587279, COSV61339621; called by mutect2, varscan2
- ANO5 | c.2010C>A p.F670L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61085792; called by muse, mutect2, varscan2
- ANOS1 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs754731969, COSV52917032; called by muse, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ANPEP | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.102); catalogued as COSV55589915; called by muse, mutect2, varscan2
- ANXA2R | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV59214665; called by muse, mutect2, varscan2
- ANXA6 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as COSV62905807; called by mutect2, varscan2
- AOC2 | c.1335C>A p.F445L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV53198461, COSV53199026; called by muse, mutect2, varscan2
- AP1S2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV61306369; called by muse, mutect2
- AP3B1 | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54877954; called by muse, mutect2, varscan2
- AP3D1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777985586; called by mutect2, varscan2
- AP3S1 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57473663; called by muse, mutect2
- AP4E1 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV55915628; called by muse, mutect2, varscan2
- AP4E1 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV55915637; called by muse, mutect2, varscan2
- APAF1 | c.3040G>A p.D1014N (on ENST00000551964 / NM_181861.2; = p.D960N on NM_001160.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs745664662, COSV59662355; called by muse, mutect2, varscan2
- APCS | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs761743822, COSV54817068; called by mutect2, varscan2
- APEH | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs147426925; called by muse, mutect2, varscan2
- APOBEC4 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.156); catalogued as COSV58017047; called by muse, mutect2, varscan2
- AQP9 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.234); catalogued as rs751975709, COSV54969502; called by muse, mutect2, varscan2
- AR | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65953973; called by muse, mutect2, varscan2
- ARAP2 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV58282364; called by muse, mutect2, varscan2
- ARFGAP2 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV60300592; called by muse, mutect2, varscan2
- ARFGEF1 | c.4214T>C p.L1405S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51604195; called by muse, mutect2, varscan2
- ARFIP1 | c.302G>A p.G101D (on ENST00000353617 / NM_001287432.1; = p.G69D on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61883507; called by muse, mutect2, varscan2
- ARHGAP22 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762382896, COSV50934645; called by muse, mutect2, varscan2
- ARHGAP30 | c.2072A>C p.D691A | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV63515273; called by muse, mutect2, varscan2
- ARHGAP31 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV51790140; called by muse, mutect2, varscan2
- ARHGAP31 | c.2981G>A p.R994K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774363849; called by muse, mutect2, varscan2
- ARHGAP42 | c.2022G>T p.Q674H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV53973168; called by muse, mutect2, varscan2
- ARHGAP44 | c.1148A>C p.K383T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52390633; called by muse, mutect2, varscan2
- ARHGAP5 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV61534341; called by muse, mutect2, varscan2
- ARHGAP9 | c.2037G>T p.K679N (on ENST00000393797 / NM_001319850.2; = p.K660N on NM_032496.4) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV57359171; called by muse, mutect2, varscan2
- ARHGEF10 | c.133A>C p.N45H (on ENST00000398564; = p.N21H on NM_014629.4) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV50643686; called by muse, mutect2, varscan2
- ARHGEF10 | c.1960G>A p.D654N (on ENST00000398564; = p.D629N on NM_014629.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs776607282, COSV50643700; called by muse, mutect2, varscan2
- ARHGEF15 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs771433483, COSV62724589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF25 | c.262T>G p.C88G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.19); catalogued as rs771640862, COSV54085090; called by mutect2, varscan2
- ARHGEF26 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV62844627; called by muse, varscan2
- ARHGEF6 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51688477; called by muse, mutect2, varscan2
- ARID2 | c.5348C>A p.S1783* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV57598770; called by muse, mutect2, varscan2
- ARL2BP | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV54656700; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs757791916, COSV64550311, COSV64551406; called by muse, mutect2, varscan2
- ARMC4 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV53463568; called by muse, mutect2, varscan2
- ARMH4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs376353516; called by muse, mutect2, varscan2
- ART3 | c.918C>A p.N306K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.086); catalogued as COSV61913413, COSV61915183; called by muse, mutect2, varscan2
- ASAP1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as rs866038991, COSV63045670; called by muse, varscan2
- ASB5 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs562003791, COSV56669215; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASCC2 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57072504; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASPH | c.1011T>G p.F337L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs746450205, COSV65243501; called by muse, mutect2, varscan2
- ASTN2 | c.2043C>A p.C681* (on ENST00000313400 / NM_001365069.1; = p.C630* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV57759093; called by muse, mutect2, varscan2
- ASXL1 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369425922, COSV60104004, COSV60108838; called by mutect2, varscan2
- ASXL3 | c.3648T>G p.I1216M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV52460439; called by muse, mutect2, varscan2
- ATAD2 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV54877333, COSV54878472; called by muse, mutect2, varscan2
- ATAD5 | c.5404C>T p.R1802* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as rs1388273738, COSV58972671, COSV58977524; called by muse, mutect2, varscan2
- ATG2B | c.4982A>C p.K1661T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55889685; called by muse, mutect2, varscan2
- ATG2B | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV63422145, COSV63424081; called by muse, mutect2, varscan2
- ATL1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs773401705, COSV63296054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs202189871; called by muse, mutect2, varscan2
- ATP11B | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV60026993; called by muse, mutect2, varscan2
- ATP11C | c.2189T>C p.L730P | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); catalogued as rs1283031975, COSV59561166; called by muse, mutect2, varscan2
- ATP13A5 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60866954; called by muse, mutect2, varscan2
- ATP5PB | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV52384801; called by muse, mutect2, varscan2
- ATP6V0A2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57748091; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1745T>G p.F582C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59473535; called by muse, mutect2, varscan2
- ATP7B | c.3555C>T p.D1185= | Splice Region (SNP) | VAF 17/99 reads (17%) | catalogued as rs756751716, COSV54436155, COSV54438842; called by muse, mutect2, varscan2
- ATP8A2 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.147); catalogued as COSV54941919; called by muse, mutect2, varscan2
- ATP8B1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV52173638; called by muse, mutect2, varscan2
- ATP8B3 | c.2346G>T p.E782D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100034680, COSV59541000; called by muse, mutect2, varscan2
- ATR | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 48/167 reads (29%) | catalogued as COSV63384844; called by muse, mutect2, varscan2
- ATRAID | c.584T>G p.I195S (on ENST00000611786; = p.I82S on NM_016085.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV53024524; called by muse, mutect2, varscan2
- ATRX | c.6409G>A p.A2137T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557060350, COSV64873095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as COSV64869351; called by muse, mutect2, varscan2
- ATXN3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV61494145; called by muse, mutect2, varscan2
- AWAT2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as COSV52142874; called by muse, mutect2, varscan2
- AXDND1 | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62640603, COSV62642324; called by muse, mutect2, varscan2
- AXDND1 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV62640873; called by muse, varscan2
- B2M | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV62563236; called by muse, varscan2
- B3GAT1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs368413334; called by muse, mutect2, varscan2
- BACH2 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766960741, COSV57583986, COSV57586999; called by muse, mutect2, varscan2
- BAIAP3 | c.2615G>A p.R872H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs148186080; called by muse, mutect2, varscan2
- BARX1 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54158856, COSV54159486; called by mutect2, varscan2
- BAZ1A | c.4054C>T p.L1352F | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as COSV62409398; called by muse, varscan2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BAZ2B | c.5138-1G>T p.X1713_splice | Splice Site (SNP) | VAF 37/101 reads (37%) | catalogued as COSV58597141, COSV58600562; called by muse, mutect2, varscan2
- BAZ2B | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs768222434, COSV99680832; called by muse, varscan2
- BBS12 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs928199736, COSV58561273; called by muse, mutect2, varscan2
- BCAR1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs558331437, COSV50779382; called by muse, mutect2, varscan2
- BCL9 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52341987; called by muse, mutect2, varscan2
- BCLAF1 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV100787150, COSV62141017; called by muse, mutect2, varscan2
- BDP1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs371948808; called by muse, mutect2, varscan2
- BDP1 | c.7658A>G p.E2553G | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV62429732; called by muse, mutect2, varscan2
- BEND2 | c.1899C>A p.N633K | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV66215291; called by muse, mutect2, varscan2
- BHLHE40 | c.353T>G p.I118S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56575075; called by muse, mutect2
- BHLHE41 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as COSV54378348, COSV54378654; called by muse, varscan2
- BICC1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1227604274, COSV54062552; called by muse, mutect2, varscan2
- BIRC3 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV54815414; called by muse, mutect2
- BIRC6 | c.2170A>C p.K724Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV70196748, COSV70207276; called by muse, mutect2, varscan2
- BIRC6 | c.2658G>T p.K886N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.627); catalogued as rs747004451, COSV70195739; called by muse, mutect2, varscan2
- BIRC6 | c.12068C>A p.S4023Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66042800; called by muse, mutect2, varscan2
- BIRC6 | c.13189G>A p.E4397K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101428569, COSV70196756; called by muse, mutect2, varscan2
- BLM | c.4014G>T p.K1338N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61922501; called by muse, mutect2, varscan2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BNC2 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV66142356; called by muse, mutect2, varscan2
- BOLL | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778462794, COSV56573586; called by muse, mutect2, varscan2
- BOLL | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56573601; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 14/57 reads (25%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- BPNT2 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs773790200, COSV52906880; called by muse, mutect2, varscan2
- BPTF | c.3537G>T p.K1179N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58833236, COSV58844037; called by muse, mutect2, varscan2
- BRAF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs770494089, COSV56105105, COSV56366111; called by muse, mutect2, varscan2
- BRCA2 | c.4477G>T p.E1493* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV66450240; called by muse, mutect2, varscan2
- BRINP3 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766898002, COSV66516327; called by muse, mutect2, varscan2
- BROX | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61799005; called by muse, mutect2, varscan2
- BTAF1 | c.3197T>G p.F1066C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as COSV56431038; called by muse, mutect2, varscan2
- BTBD11 | c.1783G>A p.D595N (on ENST00000280758 / NM_001018072.2; = p.D132N on NM_001017523.2) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs142214499, COSV55019446; called by muse, mutect2, varscan2
- BTBD8 | c.3632C>A p.S1211Y (on ENST00000636805 / NM_001376131.1; = p.S698Y on NM_015237.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs1320963159, COSV64883890; called by muse, mutect2, varscan2
- BTN2A1 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57002444; called by muse, mutect2, varscan2
- BTN2A2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as rs752299416, COSV100760576, COSV61856804; called by muse, mutect2, varscan2
- BTN2A2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767620695, COSV61856816; called by muse, mutect2, varscan2
- C10orf90 | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52951038; called by muse, mutect2, varscan2
- C11orf71 | c.432T>G p.I144M | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV57784098; called by muse, varscan2
- C12orf4 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV54206094, COSV54206669; called by muse, mutect2, varscan2
- C12orf43 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56566531; called by muse, mutect2, varscan2
- C12orf56 | c.1541C>A p.A514D (on ENST00000543942 / NM_001170633.2; = p.A354D on NM_001099676.3) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61485779; called by muse, mutect2, varscan2
- C14orf39 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 37/134 reads (28%) | catalogued as COSV100407194, COSV58780117; called by muse, mutect2, varscan2
- C18orf32 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as COSV59087137, COSV59087910; called by muse, mutect2, varscan2
- C1orf141 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs752539243, COSV63992303; called by muse, mutect2, varscan2
- C20orf194 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV52692760, COSV52695653; called by muse, mutect2, varscan2
- C2orf16 | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV62674280, COSV62675310; called by muse, mutect2, varscan2
- C2orf74 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs574904888, COSV67041493; called by muse, mutect2, varscan2
- C2orf88 | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV61409884; called by muse, mutect2, varscan2
- C3 | c.3382G>T p.E1128* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55569757, COSV55570157, COSV99837235; called by muse, mutect2
- C3AR1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs773406377, COSV50817637; called by muse, mutect2, varscan2
- C3orf18 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144985331; called by muse, mutect2, varscan2
- C3orf20 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs765984059, COSV53783252; called by muse, mutect2, varscan2
- C3orf38 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs1285309231, COSV59627517; called by muse, mutect2, varscan2
- C6orf118 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs142447513, COSV57813418; called by muse, mutect2, varscan2
- C6orf15 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs372406795; called by muse, mutect2, varscan2
- C6orf58 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV100315005; called by muse, mutect2, varscan2
- C6orf58 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV100314876; called by muse, mutect2, varscan2
- C7 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV57472129; called by muse, mutect2, varscan2
- C7orf31 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV52216411; called by muse, mutect2
- C7orf33 | c.493T>G p.S165A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV61022859; called by muse, mutect2, varscan2
- C8orf34 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61373723, COSV61385517; called by muse, mutect2, varscan2
- C8orf34 | c.780T>G p.F260L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV61373738; called by mutect2, varscan2
- C9orf57 | c.247G>A p.A83T (on ENST00000377024 / NM_001371610.1; = p.A61T on NM_001128618.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV65462526; called by muse, mutect2, varscan2
- C9orf78 | c.84-1G>T p.X28_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs566348414, COSV100204949; called by muse, mutect2, varscan2
- CABIN1 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs748459908, COSV54079064; called by muse, mutect2, varscan2
- CACHD1 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51549964; called by muse, mutect2, varscan2
- CACNA1A | c.5438C>T p.A1813V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64192362; called by muse, mutect2, varscan2
- CACNA1B | c.4026G>T p.K1342N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV53145250; called by muse, mutect2, varscan2
- CACNA1D | c.3478G>T p.E1160* (on ENST00000350061 / NM_001128840.3; = p.E1180* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV55440576; called by muse, mutect2, varscan2
- CACNA1D | c.3762G>T p.L1254F (on ENST00000350061 / NM_001128840.3; = p.L1274F on NM_000720.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV55440602; called by muse, mutect2, varscan2
- CACNA2D1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs1416010629, COSV62375073; called by muse, mutect2, varscan2
- CACNA2D4 | c.881T>G p.I294S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54946701; called by muse, mutect2, varscan2
- CACNG2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV55633018; called by muse, mutect2, varscan2
- CACNG5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV50055000; called by muse, mutect2, varscan2
- CACNG6 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs1281697505, COSV99403366; called by muse, mutect2, varscan2
- CAGE1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57075503; called by muse, mutect2, varscan2
- CALB2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs748994795, COSV56938432; called by muse, mutect2, varscan2
- CALD1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV62645938; called by muse, mutect2, varscan2
- CALD1 | c.1494C>A p.F498L (on ENST00000361675 / NM_033138.4; = p.F243L on NM_004342.7) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100723983, COSV62649842; called by muse, mutect2, varscan2
- CAMK1D | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs763942938, COSV66608333; called by muse, mutect2, varscan2
- CAMTA2 | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61833253; called by mutect2, varscan2
- CAPN14 | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV67289985; called by muse, mutect2, varscan2
- CAPRIN2 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1282439302, COSV51830350; called by muse, varscan2
- CAPRIN2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV51831146, COSV51835000; called by muse, varscan2
- CAPS2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs990856276, COSV60824412; called by muse, varscan2
- CARD6 | c.218A>C p.Q73P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV54564852; called by muse, mutect2, varscan2
- CASP8 | c.1034G>T p.C345F (on ENST00000432109 / NM_033355.3; = p.C362F on NM_001228.4) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99630463; called by muse, mutect2, varscan2
- CASP8AP2 | c.914T>G p.F305C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV52745725; called by muse, mutect2, varscan2
- CASP8AP2 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | catalogued as COSV52745731; called by muse, mutect2, varscan2
- CASP8AP2 | c.5183C>A p.S1728Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs377357235; called by muse, mutect2, varscan2
- CATSPER3 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.841); catalogued as COSV50945401; called by muse, mutect2, varscan2
- CATSPER4 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58792551; called by muse, mutect2, varscan2
- CATSPERE | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV63677169; called by muse, mutect2, varscan2
- CAVIN4 | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247178831, COSV56866765; called by muse, mutect2, varscan2
- CAVIN4 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293224, COSV56866778; called by muse, mutect2, varscan2
- CBLN2 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs867406493, COSV54050543; called by muse, mutect2, varscan2
- CCDC125 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as COSV67287762; called by muse, mutect2, varscan2
- CCDC136 | c.1908A>C p.L636F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV52797214; called by muse, varscan2
- CCDC14 | c.787T>G p.S263A (on ENST00000488653; = p.S215A on NM_022757.5) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.217); catalogued as rs759221863, COSV59943497; called by muse, mutect2, varscan2
- CCDC144A | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | catalogued as COSV100138781; called by muse, mutect2, varscan2
- CCDC146 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs552375827, COSV53544047, COSV99035595; called by mutect2, varscan2
- CCDC150 | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs747585654, COSV55874080; called by mutect2, varscan2
- CCDC158 | c.3247T>G p.L1083V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66355389; called by muse, mutect2, varscan2
- CCDC168 | c.16727G>A p.G5576E | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV100487783, COSV59419414, COSV59420974; called by muse, mutect2, varscan2
- CCDC168 | c.15170G>T p.R5057I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59419424, COSV59423408; called by muse, mutect2, varscan2
- CCDC168 | c.9194C>A p.S3065* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV59418999; called by muse, mutect2, varscan2
- CCDC168 | c.8122G>A p.D2708N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); catalogued as COSV70554787, COSV70554812; called by muse, mutect2, varscan2
- CCDC168 | c.5348G>T p.R1783I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV70554816, COSV70555244; called by muse, mutect2, varscan2
- CCDC168 | c.3104C>T p.T1035M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs189997066, COSV70554817; called by muse, mutect2, varscan2
- CCDC170 | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53340485; called by muse, mutect2
- CCDC178 | c.2317G>T p.E773* (on ENST00000383096 / NM_001105528.3; = p.E735* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 48/179 reads (27%) | catalogued as rs150180566; called by muse, mutect2, varscan2
- CCDC186 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs532080412, COSV100990995, COSV65159686; called by muse, mutect2, varscan2
- CCDC22 | c.773A>C p.Q258P | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV66050968; called by muse, mutect2, varscan2
- CCDC28A | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60424636; called by muse, mutect2, varscan2
- CCDC39 | c.1691T>G p.L564* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV56480185; called by muse, mutect2, varscan2
- CCDC39 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV56480202; called by muse, mutect2, varscan2
- CCDC63 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.127); catalogued as rs267603306, COSV57526980, COSV57531131; called by muse, mutect2, varscan2
- CCDC65 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56739238; called by muse, mutect2, varscan2
- CCDC66 | c.2551C>T p.R851* (on ENST00000394672 / NM_001353147.1; = p.R817* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as rs775693868, COSV58301567; called by muse, mutect2, varscan2
- CCDC7 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs762095619, COSV53227495, COSV99511238; called by muse, mutect2, varscan2
- CCDC73 | c.2485T>G p.F829V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58796358; called by muse, mutect2, varscan2
- CCDC73 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV58796365; called by mutect2, varscan2
- CCDC88A | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs762374538, COSV55058197; called by muse, mutect2, varscan2
- CCER1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs757218611, COSV62646243; called by mutect2, varscan2
- CCL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs780220490, COSV56774449; called by mutect2, varscan2
- CCNB1IP1 | c.827G>T p.R276I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV62302535; called by muse, mutect2, varscan2
- CCNE1 | c.144A>C p.K48N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV52903723; called by muse, mutect2, varscan2
- CCNF | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs374120930, COSV53540460; called by mutect2, varscan2
- CCNT1 | c.127A>G p.N43D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56063489; called by muse, mutect2, varscan2
- CCP110 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66816667; called by muse, mutect2, varscan2
- CCP110 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs781615627, COSV66816671; called by muse, mutect2, varscan2
- CCPG1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV60524420; called by muse, mutect2, varscan2
- CCR5 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs781713216, COSV52751000, COSV52751098; called by muse, mutect2, varscan2
- CCT6B | c.1513C>A p.L505I | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs1350083425, COSV58488218; called by muse, mutect2, varscan2
- CCT6B | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV58488224; called by muse, mutect2, varscan2
- CD14 | c.844A>C p.N282H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57370032; called by muse, mutect2, varscan2
- CD163 | c.3264G>T p.E1088D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); catalogued as rs1328891280, COSV63130486; called by muse, mutect2, varscan2
- CD19 | c.1260C>A p.F420L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.508); catalogued as rs747967568; called by muse, mutect2, varscan2
- CD1B | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV63803945; called by muse, mutect2, varscan2
- CD2 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV65644304; called by muse, mutect2, varscan2
- CD22 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369740146; called by muse, mutect2
- CD226 | c.17T>G p.L6* | Nonsense Mutation (SNP) | VAF 38/138 reads (28%) | catalogued as COSV54610679; called by muse, mutect2, varscan2
- CD300LF | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV56896214; called by muse, mutect2, varscan2
- CD33 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.105); catalogued as COSV51800449; called by muse, mutect2, varscan2
- CD80 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV51801660; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDH10 | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52573828, COSV52579029; called by muse, mutect2, varscan2
- CDH16 | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1567531455; called by muse, mutect2, varscan2
- CDH17 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1230002025, COSV50326287; called by muse, mutect2, varscan2
- CDH19 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs780158515, COSV50958391; called by muse, mutect2, varscan2
- CDH2 | c.2505C>A p.F835L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52276409, COSV52280858; called by muse, mutect2, varscan2
- CDH2 | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.171); catalogued as COSV52274168; called by muse, mutect2, varscan2
- CDH6 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV54065987, COSV54074286; called by muse, mutect2, varscan2
- CDH6 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs752932258, COSV54065993; called by mutect2, varscan2
- CDH9 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV50257308; called by muse, mutect2, varscan2
- CDH9 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV50317389, COSV99141488; called by muse, mutect2
- CDIN1 | c.591C>A p.F197L (on ENST00000437989; = p.F99L on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV57710264; called by muse, mutect2, varscan2
- CDK11A | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1238991773, COSV62264789; called by muse, mutect2, varscan2
- CDK14 | c.514G>T p.E172* (on ENST00000380050 / NM_001287135.2; = p.E154* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 47/128 reads (37%) | catalogued as COSV99726967, COSV99727612; called by muse, mutect2, varscan2
- CDK17 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as COSV54127395; called by muse, mutect2, varscan2
- CDK9 | c.278A>C p.N93T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV64723507; called by muse, varscan2
- CDKL4 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs770898977, COSV66508842; called by muse, mutect2, varscan2
- CDON | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1449837925; called by muse, mutect2, varscan2
- CDYL | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs1162407948; called by muse, varscan2
- CECR2 | c.1021C>A p.L341I (on ENST00000342247 / NM_001290047.2; = p.L178I on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52837219; called by muse, mutect2, varscan2
- CELSR1 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866727156, COSV53099652; called by muse, varscan2
- CEMIP2 | c.834A>C p.K278N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV65485961; called by muse, mutect2, varscan2
- CENPC | c.1184A>C p.Y395S | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56621806; called by muse, mutect2, varscan2
- CENPE | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs544326830, COSV54377065, COSV54377753; called by muse, mutect2, varscan2
- CENPJ | c.3532C>T p.R1178* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as rs760698184, COSV55035984; called by muse, mutect2, varscan2
- CEP170 | c.1817T>G p.F606C | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV100318142; called by muse, mutect2, varscan2
- CEP250 | c.6428C>A p.S2143Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV61168670; called by muse, mutect2, varscan2
- CEP290 | c.5991A>C p.E1997D | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58349735; called by muse, mutect2, varscan2
- CEP290 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58349751; called by muse, mutect2, varscan2
- CEP350 | c.1517C>A p.S506* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV62599840; called by muse, mutect2, varscan2
- CEP350 | c.6794A>C p.K2265T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV62599849; called by muse, mutect2, varscan2
- CEP41 | c.160A>C p.K54Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV56218828; called by muse, mutect2, varscan2
- CEP85L | c.1617G>T p.K539N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs1404682181, COSV63821157; called by muse, mutect2, varscan2
- CEP85L | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs1238493882, COSV63821205; called by muse, varscan2
- CEP97 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV59123345; called by muse, mutect2, varscan2
- CEPT1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1197932725, COSV62958662; called by muse, mutect2, varscan2
- CETN3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 54/208 reads (26%) | catalogued as COSV51617826; called by muse, mutect2, varscan2
- CFAP206 | c.1469T>G p.F490C | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51532948; called by muse, mutect2, varscan2
- CFAP221 | c.1532A>C p.K511T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV54654788; called by muse, mutect2, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, varscan2
- CFAP43 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs759746716, COSV53376864; called by muse, mutect2, varscan2
- CFAP45 | c.1079G>T p.R360I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV63648367; called by muse, mutect2, varscan2
- CFAP47 | c.5012C>T p.T1671M | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs372678439; called by muse, mutect2, varscan2
- CFAP47 | c.8819G>T p.R2940I | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV66220213, COSV66220774; called by muse, varscan2
- CFAP57 | c.1893C>A p.F631L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65263887; called by muse, mutect2, varscan2
- CFAP58 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV57211592; called by muse, varscan2
- CFAP58 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV57211244; called by muse, mutect2, varscan2
- CFAP61 | c.1660G>T p.E554* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV55622349; called by muse, mutect2, varscan2
- CFAP69 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60184696; called by muse, mutect2, varscan2
- CFAP69 | c.1036A>C p.K346Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60184704; called by muse, mutect2, varscan2
- CFAP70 | c.1799T>C p.F600S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60281610; called by muse, mutect2, varscan2
- CFAP92 | c.1134C>A p.F378L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54046593; called by mutect2, varscan2
- CFHR4 | c.1664C>T p.A555V (on ENST00000367416 / NM_001201551.2; = p.A309V on NM_006684.5) | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as rs576733857, COSV52225996; called by muse, mutect2, varscan2
- CFTR | c.1979C>A p.S660* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV50056523, COSV50125849; called by muse, mutect2, varscan2
- CHADL | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1180006061, COSV53436895; called by muse, mutect2, varscan2
- CHD1 | c.4259G>T p.R1420I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.604); catalogued as COSV52338210; called by muse, mutect2, varscan2
- CHD8 | c.2004C>A p.F668L (on ENST00000646647 / NM_001170629.2; = p.F389L on NM_020920.4) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1445246220, COSV67869656; called by muse, mutect2, varscan2
- CHD9 | c.3348G>T p.K1116N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs539361982, COSV54608521; called by mutect2, varscan2
- CHEK2 | c.588A>C p.K196N (on ENST00000382580 / NM_001005735.2; = p.K153N on NM_007194.4) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV60417247; called by muse, mutect2, varscan2
- CHI3L2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs138664314, COSV63873542; called by muse, mutect2, varscan2
- CHIA | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs752677743, COSV58474195; called by muse, mutect2, varscan2
- CHIC1 | c.405A>C p.K135N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV65155881; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, varscan2
- CHL1 | c.686C>A p.S229Y (on ENST00000397491 / NM_001253387.1; = p.S245Y on NM_006614.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as COSV56588667; called by muse, mutect2, varscan2
- CHN1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as rs1439551726, COSV69295381; called by muse, mutect2, varscan2
- CHRD | c.2292G>T p.E764D | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV52606144; called by muse, mutect2, varscan2
- CHRDL2 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as COSV55221927; called by muse, mutect2, varscan2
- CHST10 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.795); catalogued as COSV99958842; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CHUK | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV64917427; called by muse, mutect2, varscan2
- CIC | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs763033756, COSV50550963; called by muse, mutect2, varscan2
- CKAP2 | c.911C>A p.S304Y (on ENST00000378037 / NM_001098525.2; = p.S303Y on NM_018204.5) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV51621208; called by muse, mutect2, varscan2
- CKAP2 | c.1636A>C p.K546Q (on ENST00000378037 / NM_001098525.2; = p.K545Q on NM_018204.5) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV51621217; called by muse, mutect2, varscan2
- CKAP2L | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs573603070, COSV56695920; called by muse, mutect2, varscan2
- CLCA1 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV52325833; called by muse, mutect2, varscan2
- CLCA1 | c.2699A>C p.K900T | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.156); catalogued as COSV52325852; called by muse, varscan2
- CLCA2 | c.2181G>T p.R727S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV65286532; called by muse, mutect2, varscan2
- CLCN1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs189963844, CM993827; ClinVar: uncertain significance; called by mutect2, varscan2
- CLCN2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs760164094, COSV55599346; called by muse, mutect2, varscan2
- CLDN18 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV104386110, COSV51736103; called by muse, mutect2, varscan2
- CLEC2D | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV51992769; called by muse, mutect2, varscan2
- CLEC4E | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs774391906, COSV55225250; called by muse, mutect2, varscan2
- CLEC4F | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV55478546; called by muse, mutect2, varscan2
- CLHC1 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68463726; called by muse, mutect2, varscan2
- CLK1 | c.1394G>T p.R465I | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58432584; called by muse, mutect2, varscan2
- CLNK | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV57011995; called by muse, mutect2, varscan2
- CLOCK | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV59400792; called by muse, mutect2, varscan2
- CLRN2 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs770801682, COSV71825166; called by muse, varscan2
- CLSTN3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56936547; called by muse, mutect2, varscan2
- CLTB | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs372564708; called by muse, mutect2, varscan2
- CLUL1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.454); catalogued as rs753466551, COSV100621034, COSV58111541, COSV58111821; called by muse, mutect2, varscan2
- CMYA5 | c.3778C>A p.L1260I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1193096769, COSV71404537; called by muse, mutect2, varscan2
- CNGA2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs377556030, COSV61703643, COSV61704778; called by muse, mutect2, varscan2
- CNGB3 | c.1600T>G p.Y534D | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60686297; called by muse, mutect2, varscan2
- CNKSR1 | c.1398G>T p.K466N (on ENST00000374253 / NM_001297647.2; = p.K459N on NM_006314.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58792534; called by muse, mutect2, varscan2
- CNKSR2 | c.249A>C p.E83D | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.82); PolyPhen benign (0.145); catalogued as COSV54250465; called by muse, mutect2, varscan2
- CNKSR2 | c.2375C>A p.S792Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV54252096; called by muse, mutect2, varscan2
- CNOT1 | c.1851G>T p.M617I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57766473; called by muse, mutect2
- CNOT1 | c.751A>C p.M251L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57766486; called by muse, mutect2, varscan2
- CNOT2 | c.1182T>G p.N394K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV57501583; called by muse, mutect2, varscan2
- CNOT6L | c.1476C>A p.F492L (on ENST00000504123 / NM_001286790.2; = p.F487L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV53702788, COSV99362350; called by muse, varscan2
- CNTLN | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs755471771, COSV52069929; called by muse, mutect2, varscan2
- CNTN5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1215380044, COSV54283284, COSV54294122; called by muse, mutect2
- CNTN5 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs371358971; called by muse, mutect2, varscan2
- CNTNAP3 | c.3256C>A p.Q1086K | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV99905927; called by mutect2, varscan2
- CNTNAP4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1014910351, COSV56669618; called by muse, mutect2, varscan2
- CNTNAP4 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs528691365, COSV56669638; called by muse, mutect2, varscan2
- CNTNAP5 | c.2702C>T p.S901L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs756576914, COSV70472877; called by muse, mutect2, varscan2
- CNTROB | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV66607893, COSV66608066; called by muse, mutect2, varscan2
- CNTROB | c.2308C>A p.L770I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV66607767; called by muse, mutect2, varscan2
- COG2 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs973011008, COSV64186171; called by muse, mutect2, varscan2
- COL12A1 | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.304); catalogued as rs781463654, COSV59393235; called by mutect2, varscan2
- COL13A1 | c.1201G>A p.E401K (on ENST00000398978 / NM_001130103.2; = p.E344K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1440375004, COSV62567877; called by muse, mutect2, varscan2
- COL13A1 | c.1656G>T p.E552D (on ENST00000398978 / NM_001130103.2; = p.E533D on NM_080800.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.279); catalogued as rs1294173045, COSV62567887; called by muse, mutect2, varscan2
- COL14A1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52848487; called by muse, mutect2, varscan2
- COL19A1 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs760394075, COSV59567974; called by muse, mutect2, varscan2
- COL1A2 | c.2623C>A p.L875I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51954633; called by muse, mutect2, varscan2
- COL22A1 | c.2444G>A p.R815K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.759); catalogued as COSV57328019; called by muse, mutect2, varscan2
- COL24A1 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65304646, COSV65314258; called by muse, mutect2
- COL24A1 | c.3169C>T p.L1057F | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV65303368; called by muse, mutect2, varscan2
- COL24A1 | c.1345A>C p.K449Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV65303376, COSV65315078; called by muse, mutect2, varscan2
- COL3A1 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.721); catalogued as COSV58583913; called by muse, mutect2, varscan2
- COL4A2 | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374458070; called by muse, mutect2, varscan2
- COL6A5 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV55195686, COSV55196777; called by muse, mutect2, varscan2
- COL6A5 | c.3880T>G p.F1294V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55195696; called by muse, mutect2, varscan2
- COL9A2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs763798270, COSV65607229; called by muse, mutect2, varscan2
- COPA | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV54099440; called by muse, mutect2, varscan2
- COPS2 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV54644527; called by muse, mutect2, varscan2
- COPS4 | c.505A>C p.N169H | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52313980; called by muse, mutect2, varscan2
- COQ8A | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs765825787, COSV64656698; called by muse, mutect2, varscan2
- CPA5 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV62569028; called by muse, mutect2
- CPED1 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59998638; called by muse, mutect2, varscan2
- CPNE8 | c.1483T>C p.Y495H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.195); catalogued as COSV58839709; called by muse, mutect2, varscan2
- CPNE8 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV58839718, COSV58852314; called by muse, mutect2, varscan2
- CPNE8 | c.483G>T p.L161F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.148); catalogued as COSV58839727; called by muse, mutect2, varscan2
- CPSF2 | c.1496A>C p.K499T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as COSV54097423; called by muse, mutect2, varscan2
- CR1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV65456666, COSV65459135, COSV65460002; called by muse, mutect2, varscan2
- CR1 | c.4824C>A p.F1608L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65456676; called by muse, mutect2, varscan2
- CRAT | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs377014991; called by muse, mutect2, varscan2
- CRB1 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as rs1449692232; called by muse, mutect2, varscan2
- CRLF1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs780528096, COSV66504280, COSV66505636; called by muse, mutect2, varscan2
- CRMP1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs777531665, COSV61478389; called by muse, mutect2, varscan2
- CROCC | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768236725, COSV65010703; called by muse, mutect2, varscan2
- CSDE1 | c.1647C>A p.F549L (on ENST00000358528 / NM_001007553.3; = p.F518L on NM_007158.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as COSV54741178; called by muse, mutect2, varscan2
- CSF1R | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as rs758322216, COSV53830631; called by muse, mutect2, varscan2
- CSF2RA | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as rs201854740, COSV100818008, COSV62623853; called by muse, mutect2, varscan2
- CSMD1 | c.9982T>C p.S3328P (on ENST00000520002; = p.S3327P on NM_033225.6) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs1563177858, COSV59294966; called by muse, varscan2
- CSMD1 | c.2861C>A p.S954Y (on ENST00000520002; = p.S953Y on NM_033225.6) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59295010; called by muse, mutect2, varscan2
- CSMD1 | c.217T>C p.S73P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV68178695; called by muse, mutect2, varscan2
- CSMD3 | c.10651C>T p.R3551C (on ENST00000297405 / NM_001363185.1; = p.R3382C on NM_052900.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747094531, COSV52118225, COSV99830646, COSV99853569; called by muse, mutect2, varscan2
- CSMD3 | c.6014G>T p.R2005I (on ENST00000297405 / NM_001363185.1; = p.R1901I on NM_052900.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV52281828; called by muse, mutect2
- CSNK1A1L | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.911); catalogued as rs776982240, COSV65789443, COSV65790164; called by muse, mutect2, varscan2
- CSPP1 | c.647G>T p.R216I (on ENST00000676605; = p.R175I on NM_024790.6) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV51581355; called by muse, mutect2, varscan2
- CSTL1 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55677803; called by muse, mutect2
- CTAGE1 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66943073, COSV66944362; called by muse, mutect2
- CTAGE9 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs199637587, COSV100020663; called by muse, mutect2, varscan2
- CTCFL | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs765675257, COSV54773669; called by muse, mutect2, varscan2
- CTNNA1 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1308395731, COSV57070813; called by muse, mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 62/117 reads (53%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs745947461, COSV63552800; called by muse, mutect2, varscan2
- CTNNA2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753550582, COSV58139782, COSV58140798; called by muse, mutect2, varscan2
- CTNNA2 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as COSV58140810; called by muse, mutect2, varscan2
- CTNNB1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV62692261; called by muse, mutect2, varscan2
- CTNNB1 | c.1956G>A p.A652= | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as COSV62693132; called by muse, mutect2, varscan2
- CTR9 | c.1031T>G p.F344C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV63728071; called by muse, mutect2, varscan2
- CUBN | c.8551T>G p.F2851V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64710069; called by muse, mutect2, varscan2
- CUBN | c.4752G>T p.E1584D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64710081; called by muse, mutect2, varscan2
- CUBN | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV64701308; called by muse, mutect2, varscan2
- CUBN | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV64701318; called by muse, mutect2, varscan2
- CUL5 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV67610054; called by muse, varscan2
- CUL9 | c.5632C>T p.R1878C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759125679, COSV52725262, COSV99334941; called by mutect2, varscan2
- CWF19L1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV62499040; called by muse, mutect2, varscan2
- CWF19L2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV56508888; called by muse, mutect2, varscan2
- CXCL16 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756648834, COSV52640419; called by muse, mutect2, varscan2
- CYP17A1 | c.1140-1G>A p.X380_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV64004777; called by muse, mutect2, varscan2
- CYP2A7 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309372701, COSV52498967; called by muse, mutect2, varscan2
- CYP2C18 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as rs1484221641, COSV53672088; called by muse, mutect2, varscan2
- CYP2C19 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64907136, COSV64909041; called by muse, mutect2, varscan2
- CYP3A4 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV100316008, COSV60502547; called by muse, mutect2, varscan2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by muse, mutect2, varscan2
- CYTH1 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV63119149; called by muse, mutect2, varscan2
- DBF4 | c.187A>C p.K63Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV55996145; called by muse, mutect2, varscan2
- DBI | c.246G>T p.K82N (on ENST00000355857 / NM_001079862.3; = p.K99N on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.752); catalogued as COSV61055528; called by muse, mutect2, varscan2
- DCAF1 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as COSV60041329; called by muse, mutect2, varscan2
- DCAF11 | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58108510; called by muse, mutect2, varscan2
- DCAF4L2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60477184, COSV60480639; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DCDC1 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV60836602; called by muse, mutect2, varscan2
- DCLRE1B | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as rs774706467, COSV56723834; called by muse, mutect2, varscan2
- DCT | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65467922; called by muse, mutect2, varscan2
- DCTN3 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV52406727; called by muse, mutect2, varscan2
- DDC | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV63564269; called by muse, mutect2, varscan2
- DDX10 | c.526A>C p.I176L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV59432439; called by muse, mutect2, varscan2
- DDX18 | c.1898A>C p.K633T | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54305709; called by muse, varscan2
- DDX20 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs753843841, COSV63777699; called by muse, mutect2, varscan2
- DDX24 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58211988; called by muse, mutect2, varscan2
- DDX27 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV65595115; called by muse, mutect2, varscan2
- DDX4 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61753564, COSV61755076; called by muse, varscan2
- DDX42 | c.720T>G p.N240K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.554); catalogued as COSV63789587; called by muse, mutect2, varscan2
- DEFB106B | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs1441760175, COSV59176023; called by muse, mutect2, varscan2
- DEFB114 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1193300033, COSV59037177, COSV59037299; called by muse, mutect2, varscan2
- DEFB115 | c.13C>A p.H5N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.122); catalogued as COSV68723004; called by muse, mutect2, varscan2
- DENND10 | c.545G>T p.R182I | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63857366; called by muse, mutect2, varscan2
- DENND10 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV100814014, COSV63857404; called by muse, mutect2, varscan2
- DENND11 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774706582, COSV72097616; called by muse, mutect2, varscan2
- DENND2C | c.2701G>A p.E901K (on ENST00000393274 / NM_001256404.2; = p.E844K on NM_198459.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV67920389; called by muse, mutect2, varscan2
- DENND4C | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.928); catalogued as rs772654971, COSV66821581; called by muse, mutect2, varscan2
- DENND4C | c.4097G>A p.R1366Q (on ENST00000434457 / NM_001330640.2; = p.R1317Q on NM_017925.7) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs975704287, COSV63008469; called by muse, mutect2, varscan2
- DENND5A | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1231023959, COSV60232166; called by mutect2, varscan2
- DEPDC7 | c.1491C>A p.F497L (on ENST00000241051 / NM_001077242.2; = p.F488L on NM_139160.2) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV53806278; called by muse, mutect2, varscan2
- DERL2 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as COSV50147035; called by muse, mutect2, varscan2
- DGKI | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs778003452, COSV55940907; called by muse, mutect2, varscan2
- DGKI | c.1099A>C p.K367Q | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55940936; called by muse, mutect2, varscan2
- DHRS7 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.024); catalogued as COSV53665499; called by muse, mutect2
- DHX15 | c.2357A>C p.K786T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV61026018; called by muse, mutect2, varscan2
- DIAPH2 | c.2973C>A p.F991L | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV61263010; called by muse, mutect2, varscan2
- DIP2A | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100595124; called by muse, mutect2, varscan2
- DIS3L | c.1132C>T p.R378* (on ENST00000319212 / NM_001143688.3; = p.R295* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs893215526, COSV59911391; called by muse, mutect2, varscan2
- DISP1 | c.2080G>T p.V694L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52656075; called by muse, mutect2, varscan2
- DLC1 | c.1516T>G p.L506V (on ENST00000276297 / NM_001348081.2; = p.L69V on NM_006094.5) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52294590; called by muse, mutect2, varscan2
- DLEC1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57297761, COSV57299609; called by muse, mutect2, varscan2
- DLEC1 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57296433; called by muse, mutect2, varscan2
- DLG1 | c.2195T>G p.I732S (on ENST00000419354 / NM_001290983.1; = p.I754S on NM_004087.2) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV58379157; called by muse, mutect2, varscan2
- DLG2 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54628398; called by muse, mutect2, varscan2
- DLG2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54628183; called by muse, mutect2, varscan2
- DLG2 | c.160G>T p.E54* (on ENST00000650630 / NM_001351274.2; = p.E17* on NM_001142699.3) | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101072624, COSV65826078; called by muse, mutect2, varscan2
- DLGAP3 | c.799T>G p.L267V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52392267; called by muse, mutect2, varscan2
- DMBT1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57537363; called by muse, mutect2, varscan2
- DMD | c.3348G>T p.K1116N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV63740775; called by muse, mutect2, varscan2
- DMXL1 | c.4630C>A p.L1544I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60706611, COSV60715403; called by muse, mutect2, varscan2
- DMXL1 | c.7702C>A p.L2568I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV60706624; called by muse, mutect2, varscan2
- DMXL2 | c.6979A>C p.N2327H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.832); catalogued as COSV51842268; called by muse, mutect2, varscan2
- DMXL2 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV51842281; called by muse, mutect2, varscan2
- DNAH1 | c.7842G>T p.K2614N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV70232780; called by muse, mutect2, varscan2
- DNAH11 | c.8263G>T p.D2755Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60945006, COSV60954223; called by muse, mutect2, varscan2
- DNAH11 | c.8384A>G p.D2795G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV60960456; called by muse, varscan2
- DNAH11 | c.8441C>T p.T2814M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV60945024; called by muse, varscan2
- DNAH11 | c.11426G>A p.R3809Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs753081155, COSV60944762, COSV60945057; called by muse, mutect2, varscan2
- DNAH12 | c.8071G>T p.E2691* (on ENST00000351747; = p.E3559* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV61055939; called by muse, mutect2, varscan2
- DNAH12 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1559729982, COSV60855998; called by muse, mutect2, varscan2
- DNAH14 | c.1046G>A p.R349Q (on ENST00000445597; = p.R330Q on NM_001145154.3) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs563159604, COSV64784073; called by muse, mutect2, varscan2
- DNAH14 | c.7971T>G p.N2657K (on ENST00000445597; = p.N3460K on NM_001367479.1) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.272); catalogued as COSV59895427; called by muse, mutect2, varscan2
- DNAH17 | c.4121T>G p.F1374C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750925; called by muse, mutect2, varscan2
- DNAH2 | c.10382G>A p.R3461Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs375708908; called by mutect2, varscan2
- DNAH3 | c.8095G>T p.E2699* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV54509447, COSV54516276; called by muse, mutect2, varscan2
- DNAH3 | c.6677C>T p.S2226L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV54504780; called by muse, mutect2, varscan2
- DNAH3 | c.2426A>C p.K809T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV54509483; called by muse, varscan2
- DNAH5 | c.11228G>T p.R3743I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774599183, COSV54208065, COSV54225223; called by mutect2, varscan2
- DNAH5 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV54210520, COSV54213239; called by muse, mutect2, varscan2
- DNAH5 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749610202, COSV54203222; called by muse, varscan2
- DNAH7 | c.5596C>T p.R1866* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs762961022, COSV100414182, COSV56785723; called by mutect2, varscan2
- DNAH8 | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV59431630; called by muse, mutect2, varscan2
- DNAH8 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV59431648; called by muse, mutect2, varscan2
- DNAH8 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59424995; called by muse, mutect2, varscan2
- DNAH9 | c.7208T>C p.L2403P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV52337652; called by mutect2, varscan2
- DNAH9 | c.12406C>T p.R4136* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs372892940; called by muse, mutect2, varscan2
- DNAJB9 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.967); catalogued as COSV50811949; called by muse, mutect2, varscan2
- DNAJC13 | c.5854A>C p.N1952H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53447172; called by muse, mutect2, varscan2
- DNAJC13 | c.6337A>G p.I2113V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs746888915, COSV53447180; called by muse, mutect2, varscan2
- DNAJC4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs765246616; called by muse, mutect2, varscan2
- DNASE2B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV65743212; called by muse, mutect2, varscan2
- DND1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs770100890, COSV56908180; called by mutect2, varscan2
- DNTTIP2 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV63283699; called by muse, mutect2, varscan2
- DOCK10 | c.2999C>T p.S1000L | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1386476589, COSV51352079; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2
- DOCK4 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as rs771879680, COSV69854261; called by muse, mutect2, varscan2
- DOCK4 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV70316208; called by muse, varscan2
- DOCK8 | c.4163G>A p.R1388Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs1163735378, COSV66618581; called by muse, mutect2, varscan2
- DOCK9 | c.493G>A p.A165T (on ENST00000376460 / NM_001366676.2; = p.A166T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV59622890; called by muse, mutect2, varscan2
- DOK5 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV52817746; called by muse, mutect2, varscan2
- DOP1A | c.6368T>G p.M2123R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV52707900; called by muse, mutect2, varscan2
- DPP10 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs371613510, COSV59663784; called by muse, mutect2, varscan2
- DPP10 | c.2045T>C p.L682S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59671746; called by muse, mutect2, varscan2
- DPPA2 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72117963; called by muse, mutect2, varscan2
- DPY19L2 | c.1671G>T p.K557N | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61040087; called by muse, mutect2, varscan2
- DPY19L2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1478776218, COSV60541920; called by muse, mutect2, varscan2
- DPY19L2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV60541927; called by muse, mutect2, varscan2
- DRC1 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV56529760; called by muse, mutect2, varscan2
- DROSHA | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766022493; called by muse, mutect2, varscan2
- DSC2 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs535014010, COSV51862205; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DSC3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV64572136; called by muse, mutect2, varscan2
- DSG1 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57133946; called by muse, mutect2, varscan2
- DSG3 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57124843; called by muse, mutect2
- DSG4 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs886053705, COSV57388902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG4 | c.3018G>T p.M1006I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57389220; called by muse, mutect2, varscan2
- DSPP | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1360342395, COSV56808776; called by muse, mutect2, varscan2
- DSPP | c.3584G>A p.S1195N | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.792); catalogued as COSV56808784, COSV56811789; called by muse, mutect2, varscan2
- DST | c.8782G>T p.E2928* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV55014110; called by muse, mutect2, varscan2
- DST | c.8458G>A p.D2820N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.661); catalogued as rs372407100, COSV99750581; called by muse, mutect2, varscan2
- DST | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56805807; called by muse, mutect2, varscan2
- DTHD1 | c.940G>A p.A314T (on ENST00000456874; = p.A149T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1199013078, COSV62629974, COSV62631153; called by muse, mutect2, varscan2
- DUSP10 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV60456963; called by muse, mutect2, varscan2
- DUSP11 | c.378A>C p.K126N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV55593948; called by muse, varscan2
- DUXA | c.451A>C p.N151H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73729541; called by muse, mutect2, varscan2
- DYNC1I1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1463517537, COSV100269623; called by muse, mutect2, varscan2
- DYNC2H1 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776317704, COSV62088750; called by muse, mutect2, varscan2
- DYNC2H1 | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV62088992, COSV62094746; called by muse, mutect2, varscan2
- DYNC2I1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs370684015, COSV68107414; called by muse, mutect2, varscan2
- DYRK1A | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV58292491; called by muse, mutect2, varscan2
- DZIP1L | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV59519628; called by muse, mutect2, varscan2
- DZIP3 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV64311409; called by muse, mutect2, varscan2
- EBF1 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs774638501, COSV58169436, COSV58170601; called by muse, mutect2, varscan2
- ECT2L | c.152T>G p.F51C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV62883171; called by muse, mutect2, varscan2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2, varscan2
- EDEM2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65713110; called by muse, mutect2, varscan2
- EEF2K | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53779466; called by muse, mutect2, varscan2
- EFCAB14 | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV64238397; called by muse, mutect2, varscan2
- EFCAB6 | c.2225C>A p.S742* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53059772; called by muse, mutect2, varscan2
- EFEMP1 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV62615362; called by muse, mutect2, varscan2
- EFHC1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs77682973, COSV64135667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFHC2 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 26/43 reads (60%) | catalogued as COSV69553034, COSV69553957; called by muse, mutect2, varscan2
- EFL1 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV51603502; called by muse, mutect2, varscan2
- EFR3A | c.88-1G>T p.X30_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99603777; called by muse, mutect2, varscan2
- EGFLAM | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59295471; called by muse, varscan2
- EGLN1 | c.772T>C p.W258R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64148146; called by muse, mutect2, varscan2
- EGR4 | c.1102G>A p.A368T (on ENST00000545030; = p.A265T on NM_001965.4) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV71531939; called by muse, mutect2, varscan2
- EHD2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs373126567, COSV54409696; called by muse, mutect2
- EHMT2 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as rs1192060899; called by muse, mutect2
- EIF2S3 | c.1189A>G p.K397E | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV53406091; called by muse, mutect2, varscan2
- ELL2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550971003, COSV52983480; called by muse, mutect2, varscan2
- ELOA2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs148724194; called by muse, mutect2, varscan2
- ELP4 | c.1153C>T p.H385Y (on ENST00000350638; = p.H384Y on NM_019040.5) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs750204793, COSV63350876; called by muse, mutect2, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs746682537; called by mutect2, varscan2
- ENAM | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68535455; called by muse, mutect2, varscan2
- ENO4 | c.1025A>C p.K342T (on ENST00000622726; = p.K339T on NM_001242699.2) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1291540916, COSV58004067; called by muse, mutect2, varscan2
- ENPP2 | c.1546C>A p.L516I (on ENST00000075322 / NM_001040092.3; = p.L568I on NM_006209.5) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs1232148362, COSV50011012; called by muse, mutect2, varscan2
- ENPP3 | c.1364G>T p.R455I | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100717033; called by mutect2, varscan2
- ENPP5 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.038); catalogued as rs1235020106, COSV57908284; called by muse, mutect2, varscan2
- ENPP6 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV57066728, COSV57072151; called by muse, mutect2, varscan2
- ENSA | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV55026338; called by muse, mutect2, varscan2
- ENTHD1 | c.1636A>C p.N546H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV57318059; called by muse, mutect2, varscan2
- EP300 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs773503228, COSV54343542; called by muse, mutect2, varscan2
- EPC1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV53923772; called by muse, varscan2
- EPHA7 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV65178818; called by muse, mutect2, varscan2
- ERC2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55607737; called by muse, mutect2, varscan2
- ERG | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV55728545; called by muse, mutect2, varscan2
- ERICH3 | c.1347A>C p.K449N | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV58598382; called by muse, mutect2, varscan2
- ERICH3 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58601756; called by muse, mutect2, varscan2
- ERLIN1 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV64940884; called by muse, mutect2, varscan2
- ERMAP | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs771827271, COSV60273678; called by muse, mutect2, varscan2
- ERP27 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56762604; called by muse, mutect2, varscan2
- ESCO2 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs556131901, COSV59413836, COSV59416257; called by muse, mutect2, varscan2
- ESM1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV67318394, COSV67318491; called by muse, mutect2, varscan2
- ESRP2 | c.824G>A p.R275H (on ENST00000565858 / NM_001365264.1; = p.R265H on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748645452, COSV52172393; called by muse, mutect2, varscan2
- ESX1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65424047; called by muse, mutect2, varscan2
- ETFDH | c.1223T>G p.I408S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV57014361; called by muse, mutect2, varscan2
- ETNK1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV56883453; called by muse, mutect2, varscan2
- ETNPPL | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56594916; called by muse, mutect2, varscan2
- ETS2 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV100711408; called by muse, mutect2
- EVC | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53830136; called by muse, mutect2, varscan2
- EVC | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV53830145; called by muse, mutect2, varscan2
- EVC2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); catalogued as COSV60389108; called by muse, varscan2
- EVL | c.563C>T p.P188L (on ENST00000402714 / NM_001330221.2; = p.P190L on NM_016337.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs367737727; called by muse, mutect2, varscan2
- EXD1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV59253126; called by muse, mutect2, varscan2
- EXD3 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV59804884; called by muse, mutect2, varscan2
- EXOC4 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.814); catalogued as rs530657357, COSV104390732; called by mutect2, varscan2
- EXOC6 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV53320801; called by muse, mutect2, varscan2
- EXOC6B | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as COSV55548034; called by muse, mutect2, varscan2
- EXOSC7 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55555662; called by muse, mutect2, varscan2
- EXOSC9 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54665233; called by muse, mutect2, varscan2
3,180 further variants in this file (2,224 protein-altering or splice-affecting, 554 silent, 402 other) are not listed here.
